Somatic mutation profile of tumor specimen 0DJHH6 from CCDI case PBBWKY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.7 years (6,476 days).
Specimen 0DJHH6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f43c1c85-8720-4de7-b4ab-29490a37b33b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJHE0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bb6c3e4-3241-46b5-b7d0-cb8e1fda99c6

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 160/423 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGAP1 | c.1811C>T p.T604M (on ENST00000304032 / NM_001037131.3; = p.T551M on NM_014914.5) | Missense Mutation (SNP) | VAF 245/521 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1031246125, COSV58341212; called by muse, mutect2, varscan2
- AGAP2 | c.1432G>A p.V478I (on ENST00000547588 / NM_001122772.2; = p.V142I on NM_014770.4) | Missense Mutation (SNP) | VAF 265/959 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374777096; called by muse, mutect2, varscan2
- COX10 | c.175A>G p.M59V | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.05); catalogued as COSV55401652; called by muse, mutect2
- LPAR1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 93/524 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs187429734; called by muse, mutect2, varscan2
- MARS1 | c.1341C>A p.S447R | Missense Mutation (SNP) | VAF 266/575 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56258128; called by muse, mutect2, varscan2
- MYOCD | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 30/924 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58497340; called by muse, mutect2
- PRRC1 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 174/427 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs371106756; called by muse, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 38/1026 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- FBXW7 | c.1874G>T p.S625I (on ENST00000281708 / NM_001349798.2; = p.S545I on NM_018315.5) | Missense Mutation (SNP) | VAF 116/654 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT14 | c.1394A>G p.E465G | Missense Mutation (SNP) | VAF 281/592 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- NF1 | c.547_548del p.I183Qfs*17 | Frame Shift Del (DEL) | VAF 145/376 reads (39%) | called by pindel, varscan2
- SMC1A | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 339/357 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SUFU | c.530T>G p.M177R | Missense Mutation (SNP) | VAF 278/589 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SUFU | c.1330_1332del p.L444del | In Frame Del (DEL) | VAF 339/763 reads (44%) | called by mutect2, pindel, varscan2
- ALKBH6 | c.561C>T p.A187= (on ENST00000252984 / NM_001297701.2; = p.A215= on NM_032878.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 171/333 reads (51%) | called by muse, mutect2, varscan2
- GALK2 | c.720C>T p.F240= | Silent (SNP) | VAF 16/488 reads (3%) | called by muse, mutect2
- TP63 | c.387G>A p.S129= | Silent (SNP) | VAF 255/954 reads (27%) | catalogued as rs151335217; called by muse, mutect2, varscan2
- ZNF75A | c.177G>A p.P59= | Silent (SNP) | VAF 206/454 reads (45%) | catalogued as rs753200527, COSV73039580; called by muse, mutect2, varscan2
- FARP1 | c.2144-17A>C | Intron (SNP) | VAF 158/329 reads (48%) | called by muse, mutect2, varscan2
